Somatic mutation profile of tumor specimen C3L-02893-02 (aliquot CPT0197030006) from CPTAC case C3L-02893, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA3; Tumor grade: G2; Age at diagnosis: 72.1 years (26,331 days).
Specimen C3L-02893-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76c01b92-4c1a-4bec-b76f-fad1ab5f9110.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02893-31 (Blood Derived Normal), aliquot CPT0197820002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/477f7d53-0c0c-4ded-8fda-9a5669b44188

The open-access MAF lists 51 somatic variants for this specimen: 38 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 6, Intron 3, Nonsense Mutation 3, 3'UTR 2, Splice Region 2, 5'Flank 1, Frame Shift Ins 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2239_2247del p.L747_E749del | In Frame Del (DEL) | VAF 52/381 reads (14%) | hotspot (GDC flag); catalogued as rs121913436; ClinVar: drug response; called by pindel, varscan2
- PORCN | c.787G>A p.E263K (on ENST00000326194 / NM_203475.3; = p.E252K on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/380 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1556974682, COSV100400326; ClinVar: likely pathogenic; called by muse, mutect2
- APOBEC3B | c.917G>T p.R306L | Missense Mutation (SNP) | VAF 172/1073 reads (16%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.458); catalogued as COSV100213765; called by muse, mutect2, varscan2
- C19orf71 | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1021187614, COSV61536990; called by muse, mutect2, varscan2
- CDHR2 | c.2988C>G p.D996E | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.306); catalogued as COSV99990801; called by muse, mutect2, varscan2
- CSMD1 | c.7961C>A p.T2654K (on ENST00000520002; = p.T2653K on NM_033225.6) | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV59362540, COSV59392998; called by muse, mutect2, varscan2
- CTR9 | c.470A>G p.N157S | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV63728215; called by muse, mutect2
- EDA | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.977); catalogued as COSV65782292; called by muse, mutect2
- GAK | c.2344C>T p.P782S | Missense Mutation (SNP) | VAF 26/464 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0.021); catalogued as rs1044025916, COSV58509067; called by muse, mutect2
- KRTAP2-4 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs1215600216; called by muse, mutect2, varscan2
- LAMB1 | c.4258G>A p.E1420K | Missense Mutation (SNP) | VAF 32/678 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs564358099, COSV55967593; called by muse, mutect2
- SLC15A3 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 14/225 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs1433491729; called by muse, mutect2
- SLC9A5 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); catalogued as rs925011400; called by muse, mutect2, varscan2
- TGFBR2 | c.404T>C p.M135T | Missense Mutation (SNP) | VAF 51/304 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.076); catalogued as rs1559458941; called by muse, mutect2, varscan2
- THEMIS | c.1033C>T p.R345* | Nonsense Mutation (SNP) | VAF 13/135 reads (10%) | catalogued as COSV64069228; called by muse, mutect2, varscan2
- ZNF536 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as rs1291337078, COSV62819722; called by muse, mutect2
- ATIC | c.1184T>C p.V395A | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.277); called by muse, mutect2
- CPNE1 | c.982C>T p.Q328* (on ENST00000352393; = p.Q333* on NM_003915.5) | Nonsense Mutation (SNP) | VAF 51/117 reads (44%) | called by muse, mutect2, varscan2
- CPNE1 | c.400T>G p.L134V (on ENST00000352393; = p.L139V on NM_003915.5) | Missense Mutation (SNP) | VAF 167/398 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLEC1 | c.3326G>T p.R1109M | Missense Mutation (SNP) | VAF 83/298 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- DNMT1 | c.1222A>G p.T408A | Missense Mutation (SNP) | VAF 60/343 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- EBLN2 | c.672_673dup p.G225Vfs*8 | Frame Shift Ins (INS) | VAF 60/256 reads (23%) | called by mutect2, pindel, varscan2
- FDX2 | c.513G>C p.K171N | Missense Mutation (SNP) | VAF 85/331 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GCC1 | c.187C>A p.H63N | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.014); called by muse, mutect2
- MRPS24 | c.40-8_40-6delinsT | Splice Region (DEL) | VAF 50/261 reads (19%) | called by pindel, varscan2*
- PIK3R1 | c.839C>G p.S280C | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.418); called by muse, mutect2
- PLA2G7 | c.378T>A p.G126= | Splice Region (SNP) | VAF 49/341 reads (14%) | called by muse, mutect2, varscan2
- PRKDC | c.4021A>G p.I1341V | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- RASIP1 | c.2306C>A p.S769Y | Missense Mutation (SNP) | VAF 94/385 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RBMS1 | c.529A>T p.S177C | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.435); called by muse, mutect2
- RTL9 | c.508C>G p.P170A | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- SLC7A3 | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- TENM1 | c.4769G>T p.R1590L | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.302); called by muse, mutect2
- TMCC1 | c.1602A>C p.E534D (on ENST00000393238 / NM_001349268.2; = p.E210D on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TRIM51GP | c.205T>A p.C69S | Missense Mutation (SNP) | VAF 58/313 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TTYH1 | c.605T>A p.V202E | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- UBAP1 | c.1049C>T p.T350I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF93 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 49/242 reads (20%) | called by muse, mutect2, varscan2
- ACAA1 | c.93G>T p.P31= | Silent (SNP) | VAF 34/382 reads (9%) | called by muse, mutect2
- EXPH5 | c.150A>G p.R50= | Silent (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- IGLV3-19 | c.235C>A p.R79= | Silent (SNP) | VAF 36/285 reads (13%) | called by muse, varscan2
- OBSCN | c.13821G>A p.P4607= | Silent (SNP) | VAF 23/334 reads (7%) | catalogued as rs368964682; called by muse, mutect2
- PLA2G6 | c.171C>T p.C57= | Silent (SNP) | VAF 31/468 reads (7%) | catalogued as rs150718378, CM130770; ClinVar: likely benign; called by muse, mutect2
- ZNF729 | c.1575T>C p.F525= | Silent (SNP) | VAF 16/499 reads (3%) | called by muse, mutect2
- ARHGEF4 | chr2:130915003 G>A | 5'Flank (SNP) | VAF 13/122 reads (11%) | called by muse, mutect2, varscan2
- JPH3 | chr16:87702262 C>A | 3'Flank (SNP) | VAF 47/239 reads (20%) | called by muse, mutect2, varscan2
- KCNK10 | c.38-7241T>C | Intron (SNP) | VAF 37/218 reads (17%) | called by muse, mutect2, varscan2
- RAB18 | c.*3494C>T | 3'UTR (SNP) | VAF 41/254 reads (16%) | called by muse, mutect2, varscan2
- RASA1 | c.539+17G>T | Intron (SNP) | VAF 134/522 reads (26%) | called by muse, mutect2, varscan2
- STEAP1B | c.706-18808C>T | Intron (SNP) | VAF 52/368 reads (14%) | catalogued as rs750682063; called by muse, mutect2, varscan2
- TBX19 | c.*25A>T | 3'UTR (SNP) | VAF 64/245 reads (26%) | called by muse, mutect2, varscan2
